CCDI case PBBSTU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e6b8cac5-388e-4fe2-be1b-4713d2617ee4

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Desmoplastic nodular medulloblastoma: ICD-O-3 morphology code: 9471/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 0.8 years (286 days).

Biospecimens (3 samples)
- Sample 0DG84F: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DG857: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DG87P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
